Gene-level copy-number profile of tumor specimen TCGA-VT-A80J-01A from TCGA case TCGA-VT-A80J, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Undifferentiated sarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 49.1 years (17,925 days).
Specimen TCGA-VT-A80J-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.eb599540-bd76-47c5-b520-123d16764d48.absolute_liftover.gene_level_copy_number.v36.tsv, workflow ABSOLUTE segment calls lifted over to GRCh38 (Affymetrix SNP 6.0); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 3,829 have no estimate.
https://portal.gdc.cancer.gov/files/277ebdd6-c01f-447b-8e28-863ecf4b9a60

Most common (modal) total copy number across autosomal genes: 1 — below the diploid value of 2.
Genes by total copy number (all chromosomes): copy number 0: 579; copy number 1: 28,676; copy number 2: 23,925; copy number 3: 2,898; copy number 4: 146; copy number 5: 378; copy number 6: 149; copy number 7: 43.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VT-A80J-01A-11D-A36I-01): tumor purity 0.37, ploidy 1.6, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 579 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:586,071–4,484,375, 186 genes (broad region; genes not listed).
- chr2:241,881,363–242,160,153, 8 genes: LINC01237, LINC01238, AC093642.3, AC093642.1, AC093642.6, LINC01880, AC093642.2, LINC01881.
- chr5:795,606–5,694,742, 88 genes (broad region; genes not listed).
- chr5:114,253,513–114,253,754, 1 gene: RN7SKP89.
- chr5:116,218,026–116,218,295, 1 gene: HMGN2P27.
- chr6:76,446,988–100,890,338, 287 genes (broad region; genes not listed).
- chr11:55,903,341–55,957,630, 5 genes: OR5W1P, OR5W2, OR5I1, OR10AF1P, OR10AK1P.
- chr11:133,064,697–133,302,634, 2 genes: AP004782.1, AP003972.1.
- chr18:67,940,949–67,956,426, 1 gene: AC100844.1.

Amplified relative to the modal value (total copy number ≥ 3, i.e. more than twice the modal value of 1; autosomes only): 3,614 genes in 27 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:21,161,475–34,277,292, 439 genes, copy number 3 (broad region; genes not listed).
- chr1:53,180,921–53,186,900, 1 gene, copy number 4: AL606760.4.
- chr3:83,924,157–90,257,415, 49 genes, copy number 3–7: AC092825.1, SRRM1P2, AC117464.1, LINC00971, AC117482.1, LINC02025, AC132660.2, CADM2, MIR5688, CADM2-AS2, CADM2-AS1, THAP12P2, AC107024.1, RNU6-1129P, AC108733.1, RN7SKP284, LINC02070, AC108706.1, VGLL3, PPATP1, LINC00506, MIR4795, CHMP2B, POU1F1, KRT8P25, APOOP2, PSMC1P6, AC108749.1, RNU6-873P, HTR1F, RNU6ATAC6P, CGGBP1, AC119733.1, ZNF654, CBX5P1, C3orf38, ABCF2P1, CSNKA2IP, Y_RNA, NDUFA5P5, ICE2P2, GAPDHP50, EPHA3, AC109129.1, MTCO2P6, MTCO1P6, U3, RNU6-712P, PROS2P.
- chr3:180,989,762–198,080,720, 397 genes, copy number 5–6 (within-gene range 2–6) (broad region; genes not listed).
- chr4:53,286–107,114, 2 genes, copy number 5: ZNF595, AC253576.1.
- chr7:63,011,463–66,495,758, 142 genes, copy number 3–4 (broad region; genes not listed).
- chr7:91,880,791–100,272,218, 200 genes, copy number 3–6 (within-gene range 2–6) (broad region; genes not listed).
- chr7:100,319,222–117,323,152, 324 genes, copy number 3–5 (within-gene range 1–5) (broad region; genes not listed).
- chr7:117,332,761–117,440,780, 3 genes, copy number 3: AC002465.1, ASZ1, ANKRD49P4.
- chr8:46,671,839–88,887,573, 631 genes, copy number 3 (within-gene range 1–3) (broad region; genes not listed).
- chr8:88,808,318–89,243,793, 3 genes, copy number 3: AC090578.2, AC090578.3, RPSAP74.
- chr8:89,757,806–123,568,762, 490 genes, copy number 3–4 (within-gene range 2–4) (broad region; genes not listed).
- chr12:31,111,652–31,252,597, 3 genes, copy number 3: AC024940.1, AC024940.4, AC024940.2.
- chr12:95,020,229–95,217,482, 4 genes, copy number 3: NR2C1, FGD6, AC126615.2, AC126615.1.
- chr15:23,562,062–26,053,123, 123 genes, copy number 3–4 (broad region; genes not listed).
- chr15:46,365,836–47,134,122, 7 genes, copy number 3: AC091074.2, AC012405.1, RNU6-1014P, AC073941.1, RN7SKP101, AC073941.2, AC066615.1.
- chr15:47,272,597–47,275,164, 2 genes, copy number 3: RN7SKP139, AC084882.1.
- chr15:51,414,097–59,372,871, 163 genes, copy number 3 (broad region; genes not listed).
- chr15:63,042,632–67,255,195, 127 genes, copy number 3 (broad region; genes not listed).
- chr15:76,215,353–76,311,472, 1 gene, copy number 3 (within-gene range 1–3): ETFA.
- chr15:76,258,986–76,275,387, 2 genes, copy number 3: TYRO3P, AC027243.3.
- chr15:81,159,575–81,518,200, 9 genes, copy number 3 (within-gene range 1–3): IL16, AC103858.1, STARD5, AC103858.3, TMC3-AS1, TMC3, AC103858.2, KF456110.1, AC109809.1.
- chr19:27,638,483–39,738,029, 450 genes, copy number 3 (broad region; genes not listed).
- chr19:41,193,210–41,353,922, 8 genes, copy number 4: CYP2S1, AXL, AC011510.1, HNRNPUL1, RN7SL34P, TGFB1, AC011462.5, CCDC97.
- chr19:41,350,911–41,384,083, 2 genes, copy number 4 (within-gene range 2–4): TMEM91, B9D2.
- chr19:56,669,941–57,398,584, 31 genes, copy number 3 (within-gene range 1–3): AC006115.2, OR5AH1P, ZIM2, AC006115.1, PEG3, MIMT1, AC004792.1, AC044792.1, RPL7AP69, AC025588.4, USP29, ZIM3, AC025588.2, AC025588.3, DUXA, AC025588.1, ZNF264, AURKC, ZNF805, AC005261.3, ZNF460-AS1, ZNF460, AC005261.5, AC005261.1, AC005261.4, ZNF543, AC005261.2, ZNF304, ZNF547, TRAPPC2B, AC003002.1.
- chr21:18,686,090–18,686,164, 1 gene, copy number 4: MIR548X.

Autosomal genes at a single copy (total copy number 1): 28,676. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
